Somatic mutation profile of tumor specimen 0DFSSH from CCDI case PBBSFA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Eyelid; Age at diagnosis: 3.4 years (1,250 days).
Specimen 0DFSSH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae6d734a-ca43-44ca-ba63-27f535960983.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFSS1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/878727a9-a782-4d52-8c01-a29926bd34b1

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Nonsense Mutation 3, 3'UTR 2, 5'UTR 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 575/635 reads (91%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- STK11 | c.180C>G p.Y60* | Nonsense Mutation (SNP) | VAF 108/247 reads (44%) | catalogued as rs778376925, CD064644, CM981863, CM991149, COSV58820509, COSV58821737, COSV58821906; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABRA | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 171/881 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs767590580; called by muse, mutect2, varscan2
- CLDND1 | c.518C>A p.T173K | Missense Mutation (SNP) | VAF 195/749 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as COSV100360648; called by muse, mutect2, varscan2
- EPHX2 | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 196/957 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as rs775262679; called by muse, mutect2, varscan2
- HOXD1 | c.935C>G p.T312S | Missense Mutation (SNP) | VAF 219/933 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.009); catalogued as rs1256620475; called by muse, mutect2, varscan2
- LAMC3 | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 125/339 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs369490493; called by muse, mutect2, varscan2
- NONO | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 76/764 reads (10%) | catalogued as COSV52137416; called by muse, mutect2
- OR5H6 | c.751C>T p.R251* (on ENST00000642105; = p.R235* on NM_001005479.2) | Nonsense Mutation (SNP) | VAF 134/541 reads (25%) | catalogued as rs201434146, COSV67351164; called by muse, mutect2, varscan2
- PLEKHD1 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 82/486 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.24); catalogued as rs750455667; called by muse, mutect2, varscan2
- TRIM58 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 76/279 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753804289, COSV63569130; called by muse, mutect2, varscan2
- ARHGAP44 | c.77G>C p.S26T | Missense Mutation (SNP) | VAF 273/713 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- BCOR | c.4257del p.F1419Lfs*65 (on ENST00000378444 / NM_001123385.2; = p.F1385Lfs*65 on NM_017745.6) | Frame Shift Del (DEL) | VAF 203/492 reads (41%) | called by mutect2, varscan2
- CSMD1 | c.2671G>T p.G891C (on ENST00000520002; = p.G890C on NM_033225.6) | Missense Mutation (SNP) | VAF 208/848 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGFR4 | c.1603A>G p.N535D | Missense Mutation (SNP) | VAF 416/465 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPX6 | c.153G>C p.E51D | Missense Mutation (SNP) | VAF 211/530 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCM7 | c.2030T>A p.F677Y | Missense Mutation (SNP) | VAF 236/1323 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2652A>G p.I884M | Missense Mutation (SNP) | VAF 52/2186 reads (2%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2
- PRR32 | c.677C>G p.P226R | Missense Mutation (SNP) | VAF 138/444 reads (31%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- SOX17 | c.440G>C p.R147P | Missense Mutation (SNP) | VAF 65/299 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TRIM51GP | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 144/1158 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by mutect2, varscan2
- ADCK1 | c.1294T>C p.L432= | Silent (SNP) | VAF 181/416 reads (44%) | called by muse, mutect2, varscan2
- ASPM | c.3852A>G p.T1284= | Silent (SNP) | VAF 525/915 reads (57%) | catalogued as rs374564841; called by muse, mutect2, varscan2
- CDKN2A | c.180G>T p.A60= | Silent (SNP) | VAF 170/376 reads (45%) | catalogued as COSV58700022, COSV58724207; called by muse, mutect2, varscan2
- DOCK4 | c.5739C>T p.P1913= | Silent (SNP) | VAF 262/1021 reads (26%) | called by muse, mutect2, varscan2
- MRPL44 | c.378C>T p.S126= | Silent (SNP) | VAF 272/936 reads (29%) | catalogued as rs1191292267, COSV99285149; called by muse, mutect2, varscan2
- CACNA1A | c.5547-1101T>G | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, varscan2
- GPAA1 | c.*8C>A | 3'UTR (SNP) | VAF 149/738 reads (20%) | called by muse, mutect2, varscan2
- MAP3K7CL | c.*32T>C | 3'UTR (SNP) | VAF 88/358 reads (25%) | called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 15/154 reads (10%) | called by muse, varscan2
